Surgical pathology report (de-identified scan), TCGA case TCGA-EE-A3JD, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site University of Sydney, specimen TCGA-EE-A3JD-06A (Metastatic).

[page 1 of 2]
DOB/Age/Sex:
Location:
Requested by: UID: 39EF7A3E-370F-43FF-ABA8-9C98B3252A2D
Requested on: TCGA-EE-A3JD-06A-PR Redacted
Specimen Rcvd:
Accession No.:
Copies to:

HISTOPATHOLOGY REPORT

REFERRED MRN

CLINICAL DETAILS

Metastatic melanoma (unknown primary) - left axillary content.

FROZEN SECTION REPORT

Fresh tissue was taken for tumour banking

MACROSCOPIC DESCRIPTION

"LEFT AXILLARY CONTENTS". A piece of fatty tissue 200 x 130 x 40mm containing one large nodule. Surface inked blue, and one section taken for tumour banking not involving margins). A piece of muscle 45 x 35 x 25 is identified attached to the fibro fatty tissue.

- A. Two nodes.
- B. Four nodes.
- C. Four nodes.
- D. Four nodes.
- E. Three nodes.
- F. One bisected node.
- G. One bisected node.
- H. Three nodes.
- J & K. One node.
- L. One bisected node.
- M. One bisected node.
- N. One node.
- P. Quadresected one node.
- Q & R. Bisected one node.
- S. One node.

100-0-3
Melanoma, NOS 8720/3
Site: lymph node, axillary 077.3
JW 12/13/11

MICROSCOPIC REPORT

"LEFT AXILLARY CONTENTS"- Three of twenty six lymph nodes examined contain metastatic malignant tumour consistent with melanoma. The largest deposit measures 23mm across and more than 80% of the cross sectional area of the node is replaced by tumour. No evidence of extra nodal spread is seen in the sections examined. Immunohistochemistry was performed with the following results:

- S100 - strongly positive (nuclear and cytoplasmic)
- HMB45 - negative
- MelanA - very focally positive
- Pancytokeratin - focal weak staining

Printer

[page 2 of 2]
Requested by:

MRN/Name:

Location:

Accession:

HISTOPATHOLOGY REPORT

COMMENT

The appearances and immunohistochemical staining are consistent with metastatic malignant melanoma.

SUMMARY

LEFT AXILLARY CONTENTS:

- METASTATIC MELANOMA IN THREE OF TWENTY SIX NODES EXAMINED

REPORTED BY:

Source: NCI Genomic Data Commons file 5984aa46-6811-454c-a9f4-05cf3193cee9 (TCGA-EE-A3JD.39EF7A3E-370F-43FF-ABA8-9C98B3252A2D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).